Somatic mutation profile of tumor specimen TARGET-30-PARACS-01A (aliquot TARGET-30-PARACS-01A-01D) from TARGET case TARGET-30-PARACS, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.2 years (1,180 days).
Specimen TARGET-30-PARACS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf7c7cd7-847b-4de2-81f6-357b98ae7ae9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARACS-10A (Blood Derived Normal), aliquot TARGET-30-PARACS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8aba8f8-8811-4a8b-b8fe-2d6e954b6915

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAVIN2 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 66/154 reads (43%) | catalogued as COSV58426176; called by muse, varscan2
- EDAR | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.039); catalogued as COSV51508347; called by muse, mutect2, varscan2
- FIP1L1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV61000239; called by muse, mutect2, varscan2
- KATNAL2 | c.1077G>C p.M359I (on ENST00000356157 / NM_001353899.1; = p.M287I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV55309815; called by muse, mutect2, varscan2
- KCNA7 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV55504623; called by muse, mutect2, varscan2
- KLK14 | c.424T>A p.S142T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.14); catalogued as COSV50071698; called by muse, mutect2, varscan2
- LMNTD1 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.909); catalogued as COSV51451229; called by muse, mutect2, varscan2
- NPFFR2 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV58146522, COSV58155240; called by muse, mutect2, varscan2
- NXPH2 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55647401; called by muse, mutect2, varscan2
- PKD2L2 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV51802237; called by muse, varscan2
- RIBC2 | c.276G>C p.R92S | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); catalogued as COSV61582389; called by muse, mutect2, varscan2
- SIM2 | c.457+1G>T p.X153_splice | Splice Site (SNP) | VAF 45/119 reads (38%) | catalogued as COSV51773502; called by muse, mutect2, varscan2
- UGGT2 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV65026146; called by muse, mutect2, varscan2
- UGT2A3 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52362370; called by muse, mutect2, varscan2
- VAPA | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61299536; called by muse, mutect2, varscan2
- VILL | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52188439; called by muse, mutect2, varscan2
- LGI4 | c.1181_1197del p.G394Afs*83 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel
- FOXD4 | c.324G>C p.S108= | Silent (SNP) | VAF 52/357 reads (15%) | catalogued as COSV58703526; called by muse, varscan2
- LUC7L | c.222A>T p.A74= | Silent (SNP) | VAF 75/216 reads (35%) | catalogued as COSV53460969; called by muse, mutect2, varscan2
- NFRKB | c.3471A>T p.T1157= (on ENST00000446488 / NM_001143835.2; = p.T1182= on NM_006165.3) | Silent (SNP) | VAF 72/81 reads (89%) | catalogued as rs779105806, COSV58760862; called by muse, mutect2, varscan2
- PNPLA6 | c.3480G>T p.G1160= (on ENST00000414982 / NM_001166111.2; = p.G1112= on NM_006702.5) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55386170, COSV99653051; called by muse, mutect2, varscan2
- SORCS3 | c.2640G>A p.K880= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV63799170; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827800 C>A | 3'Flank (SNP) | VAF 14/42 reads (33%) | catalogued as COSV59423985; called by muse, mutect2, varscan2
